Surgical pathology report (de-identified scan), TCGA case TCGA-BC-4072, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site UNC, specimen TCGA-BC-4072-01B (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY

Number :

Collection Date :

1CD-0-3

Carcinoma, hepatocellular, Nos 8170/3

Site: Liver C22-0

pw 7/5/11

Collected:

Received:

Completed:

Surgical Pathology Report

Diagnosis:

A: Lymph node, portal, biopsy.

- No tumor seen in one lymph node (0/1).

B: Lymph node #2, portal, biopsy.

- No tumor seen in one lymph node (0/1).

C: Liver, segment 5 and 6, partial hepatectomy.

- Moderate to poorly differentiated hepatocellular carcinoma, multiple nodules measuring up to 4.5 cm. (see comment)

- Surgical margin measure 2.0 cm away.

D: Liver, porta hepatis mass, resection.

- Poorly differentiated hepatocellular carcinoma, size=5.6 cm

- Soft tissue margin involved by carcinoma.

- Small fragment of adherent pancreatic tissue with no tumor seen

E: Liver, segment 3, biopsy.

- Poorly differentiated hepatocellular carcinoma, size=2mm

- Surgical margin negative.

Comment:

Sections from specimens C,D, and E show a malignant neoplasm which is morphologically consistent with moderately differentiated hepatocellular carcinoma but appears poorly differentiated in several areas with pseudoacinar formation and abundant necrosis. Immunostains

Reviewed Initials	pw 7/5/11	6224

[page 2 of 3]
for AFP show strong positive staining in a section from the segment 5-6 liver tumor (C3) and focal positivity in the porta hepatis mass (D1). A reticulin stain performed on FSC1 and C1 show thickened hepatocyte trabeculae. The findings are consistent with hepatocellular carcinoma.

Intraoperative Consult Diagnosis:
Frozen section is requested by Dr.

FSA1: Lymph node, portal, biopsy
- No tumor seen in one lymph node (0/1)

FSB1: Lymph node #2, portal, biopsy
- No tumor seen in one lymph node (0/1)

FSC1: Liver, partial hepatectomy
- Hepatocellular carcinoma

Frozen Section Pathologist:

Clinical History:
history of hepatocellular carcinoma.

Gross Description:
Received are three appropriately labeled containers.

Specimen: A
SITE: "Hepatic portal"
METHOD: Biopsy
MEASURE: 1.5 x 1.0 x 0.8 cm
COMMENT: Fragment of tan/brown soft tissue. A portion was submitted as FSA1. In addition, a portion was given to tissue procurement.
BLOCK: FSA1 - frozen section remnant
A1 - remainder of soft tissue, entirely submitted

Specimen: B
SITE: "Hepatic portal #2"
METHOD: Biopsy
MEASURE: 3.2 x 2.0 x 0.9 cm
COMMENT: Single fragment of light tan rubbery soft tissue consistent with lymph node. A portion was submitted as addition, a portion was given to tissue procurement.

[page 3 of 3]
SITE: "Segment 3 liver"

METHOD: Biopsy

MEASURE: 0.6 x 0.5 x 0.2 cm in aggregate

COMMENT: A single tan/brown soft tissue fragment

BLOCK: E1

Light Microscopy:

Light microscopic examination is performed by Dr.

Source: NCI Genomic Data Commons file 710ae4a6-e0c7-434c-b730-dee9f8409b70 (TCGA-BC-4072.CF0E1E81-A89B-4D33-A02E-C77DAE5E8E30.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).